Somatic mutation profile of tumor specimen 0DX4FP from CCDI case PBCPVC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 14.9 years (5,439 days).
Specimen 0DX4FP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e45b9711-a145-4da0-ae90-6f019ef80c0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX4ET (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6916d98e-c24d-4099-9a9b-a265f7b58c4f

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FSIP2 | c.15049T>C p.Y5017H | Missense Mutation (SNP) | VAF 154/376 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs1559033936; called by muse, mutect2, varscan2
- GTF3C1 | c.4540C>G p.R1514G | Missense Mutation (SNP) | VAF 155/264 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV62240929; called by muse, mutect2, varscan2
- PAK2 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 234/408 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV59084578; called by muse, mutect2, varscan2
- POLQ | c.6221G>A p.R2074H | Missense Mutation (SNP) | VAF 85/307 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs548651855; called by muse, mutect2, varscan2
- WDR87 | c.3406G>A p.V1136I | Missense Mutation (SNP) | VAF 140/316 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as rs971265866, COSV58194120; called by muse, mutect2, varscan2
- MCRS1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 173/398 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 14/494 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- GIMAP1 | c.909C>T p.V303= | Silent (SNP) | VAF 147/288 reads (51%) | catalogued as rs573193854, COSV56189546; called by muse, mutect2, varscan2
- ISG20L2 | c.153G>A p.A51= | Silent (SNP) | VAF 56/1068 reads (5%) | catalogued as rs752017953, COSV100493948; called by muse, mutect2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 12/487 reads (2%) | catalogued as rs1267156464; called by muse, mutect2
- ZNF701 | c.1278C>T p.D426= (on ENST00000301093; = p.D360= on NM_018260.3) | Silent (SNP) | VAF 148/371 reads (40%) | called by muse, mutect2, varscan2
- TRIM4 | c.-13G>A | 5'UTR (SNP) | VAF 66/125 reads (53%) | catalogued as rs1178749441; called by muse, mutect2, varscan2
